TCGA case TCGA-JV-A75J — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cd8637c0-1651-4e8a-9a88-7fb06dc36ff8

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 43 years; Vital status: Dead; Days to death: 119 days.

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 43.8 years (16,001 days); Year of diagnosis: 2013; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Sites of involvement: Small intestine / Appendix / Omentum / Pelvis / Diaphragm / Uterus; Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 12; Tumor length measurement: 13; Tumor width measurement: 13.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 12; Tumor length measurement: 18; Tumor width measurement: 18.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 9.
- Days to follow up: 119 days; Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 68.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-JV-A75J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-JV-A75J-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-JV-A75J-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-JV-A75J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Positive; Tumor total necrosis: Extensive Necrosis (>50%); Disease multifocal indicator: Yes; Discontinuous lesions count: 9; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: small bowel, diagphragm, omentum, appendix and pelvic implant; Contiguous organ resection: Small Bowel, Mucosa only; Contiguous organ invaded: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 19; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 19; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 119 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 119 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 119 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-JV-A75J-01A-11D-A32H-01): tumor purity 0.99, ploidy 2.02, whole-genome doublings 0.
